TCGA case TCGA-YF-AA3L — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Puerto Rico. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/661967e5-94b3-4f98-9402-6ab137893c16

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Country of residence at enrollment: Puerto Rico; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.2; Tissue or organ of origin: Lateral wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 47.3 years (17,268 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 364 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 8; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 214 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 215 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 242 days; Disease response: Tumor Free.
- Days to follow up: 364 days; Disease response: Tumor Free.
- Karnofsky performance status: 30.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 112 kg; Height: 183 cm; BMI: 33.4.

Exposures
- Occupation duration years: 29; Occupation type: Other.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 60; Age at onset: 17.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Gynecologic Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YF-AA3L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 80 mg.
  Slide TCGA-YF-AA3L-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-YF-AA3L-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YF-AA3L-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: Housewife; Occupation primary: Housewife; Occupation primary industry: Home; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Lateral; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 364 days; disease-specific survival: no event (censored), 364 days; disease-free interval: no event (censored), 364 days; progression-free interval: no event (censored), 364 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YF-AA3L-01A-11D-A38F-01): tumor purity 0.91, ploidy 3.65, whole-genome doublings 1.
